Surgical pathology report (de-identified scan), TCGA case TCGA-NF-A4WX, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-NF-A4WX-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3.
Carcinosarcoma/mixed
Mullerian Tumor, malignant
895013
Site- Path: Endometrium
C54.1
C6CF: Uterus NOS
C55.9
9/21/13

SLIDE DISPOSITION:

DIAGNOSIS:

A. Soft tissue, left paracolic gutter nodule, excision: Metastatic carcinosarcoma.

B. Uterus, left and right fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy: Malignant mixed Mullerian tumor, with 80% glandular, 20% stromal differentiation, is identified forming a lobulated polypoid mass (3.7 x 3.4 x 2.4 cm). The tumor does not involve cervix. No invasion into the myometrium. Lymphovascular space invasion is identified. The tumor involves the anterior uterine serosa (0.3 cm nodule) and the left fallopian tube serosa (0.2 cm nodule). There is endometriosis on the right ovarian surface and in the uterine cul de sac. There are multiple (5 subserosal, ranging in size from 0.3 cm to 7.0 cm in greatest dimension; 10 submucosal, ranging in size from 0.1 cm to 2.4 cm in greatest dimension; 6 intramural, ranging in size from 0.3 cm to 2.0 cm in greatest dimension) leiomyomata in the myometrium. The cervix is without diagnostic abnormality. The left ovary and right fallopian tube are unremarkable.

C. Lymph nodes, left and right pelvic, excision: Multiple (24) lymph nodes are negative for tumor.

D. Omentum, omentectomy: Omentum and multiple (2) benign lymph nodes are negative for tumor.

E. Lymph nodes, right para-aortic, excision: Multiple (4) lymph nodes are negative for tumor.

F. Gonadal vessel, right, excision: Negative for tumor.

G. Lymph nodes, left para-aortic, excision: Multiple (7) lymph nodes are negative for tumor.

H. Gonadal vessel, left, excision: Negative for tumor.

I. Mesentery, sigmoid, excision: Metastatic carcinosarcoma forming a 1.3 x 1.0 x 0.4 cm friable tan mass.

J. Appendix, appendectomy: without diagnostic abnormality.

with available surgical material [AJCC pT3aN0] (7th edition,

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "left paracolic gutter tumor nodule" is a 1.8 x 1.3 x 0.4 cm portion of tan-red cauterized adipose tissue. No discrete mass is identified. All submitted.

B. Received fresh labeled "uterus, left and right fallopian tube and ovary" is a 195.0 gram uterus with bilateral fallopian tubes and ovaries. The anterior uterine serosa has hemorrhagic adhesions and the cul-de-sac has focal fibrous adhesions. There is a 3.7 x 3.4 x 2.4 cm lobulated polypoid mass attached to the left posterior wall

[page 2 of 2]
of the endometrial cavity without invasion, grossly. The myometrial thickness is 1.2 cm. There are multiple (5 subserosal, ranging in size from 0.3 cm to 7.0 cm in greatest dimension; 10 submucosal, ranging in size from 0.1 cm to 2.4 cm in greatest dimension; 6 intramural, ranging in size from 0.3 cm to 2.0 cm in greatest dimension) leiomyomata in the myometrium. There is an attached 2.8 x 1.6 x 1.4 cm right ovary with hemorrhagic adhesions on its outer surface and a cystic and solid cut surface with a 7.4 x 0.4 cm right fallopian tube, which is unremarkable. There is a detached 2.2 x 1.4 x 1.1 cm left ovary with a smooth outer surface and a solid cut surface with a 0.4 x 0.3 x 0.3 cm nodule, and a 7.2 x 0.4 cm left fallopian tube with hemorrhagic adhesions. Representative sections are submitted.

C. Received fresh labeled "left and right pelvic lymph nodes" is a 6.7 x 6.2 x 1.8 cm aggregate of adipose and lymphatic tissue. Multiple (28) lymph nodes are identified. All lymph nodes submitted.

D. Received fresh labeled "omentum" is a 36.3 x 24.4 x 1.7 cm portion of omentum. There are areas of hemorrhage, but no masses are identified grossly. Multiple (2) lymph nodes are identified. Representative sections are submitted.

E. Received fresh labeled "right para-aortic lymph nodes" is a 4.4 x 3.0 x 1.4 cm aggregate of adipose and lymphatic tissue. Multiple (5) lymph nodes are identified. All lymph nodes submitted.

F. Received fresh labeled "right gonadal vessels" is a 10.3 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel with attached adipose tissue. Representative sections submitted.

G. Received fresh labeled "left para-aortic lymph nodes" is a 3.2 x 2.2 x 1.3 cm aggregate of adipose and lymphatic tissue. Multiple (7) lymph nodes are identified. All lymph nodes submitted.

H. Received fresh labeled "gonadal vessel" is an 11.2 cm in length by 0.3 cm in diameter portion of unremarkable blood vessel with attached adipose tissue. Representative sections submitted.

I. Received fresh labeled "sigmoid mesentery biopsy" is a 2.7 x 1.5 x 0.8 cm portion of adipose tissue with a 1.3 x 1.0 x 0.4 cm friable tan mass. All submitted.

J. Received fresh labeled "appendix" is a 5.4 x 0.3 cm appendix with smooth serosa. There is no gross perforation. Representative sections are submitted.

Source: NCI Genomic Data Commons file b98e7bd5-5b10-4af4-98c7-2020ef96d18e (TCGA-NF-A4WX.C49AEF18-EE85-4113-856B-6E2B7BE7576A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).